MMRF case MMRF_1801 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/55f38380-cd5f-4979-8280-e5aeae77dee1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.0 years (23,020 days); ISS stage: I; Days to last known disease status: 635 days (1.7 years); Days to last follow up: 635 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 84 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 87 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 102 days; Days to treatment end: 102 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 127 days; Days to treatment end: 127 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 128 days; Days to treatment end: 128 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 295 days; Days to treatment end: 298 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 297 days; Days to treatment end: 297 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 299 days; Days to treatment end: 299 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 1): M Protein 1.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.647 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.432 mg/dL; Immunoglobulin G 18.3 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.23 µg/mL; Lactate Dehydrogenase 1.68 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 363 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 4.18 mmol/L.
- Day 92 (ECOG 1): M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.109 mg/dL; Immunoglobulin G 4.43 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.59 µg/mL; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 5.3 g/dL; Glucose 4.07 mmol/L.
- Day 232 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 5.35 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 1.36 µg/mL; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 6.1 g/dL; Glucose 4.62 mmol/L.
- Day 338 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 3.73 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 1.19 µg/mL; Lactate Dehydrogenase 8.89 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 21 ×10⁹/L; Absolute Neutrophil 20 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 5.5 g/dL; Glucose 5.5 mmol/L.
- Day 457 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.588 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.242 mg/dL; Immunoglobulin G 5.09 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 5.5 g/dL; Glucose 4.57 mmol/L.
- Day 544 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.456 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.26 mg/dL; Immunoglobulin G 4.77 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.2 µg/mL; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 5.9 g/dL; Glucose 4.9 mmol/L.
- Day 635 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.596 mg/dL; Immunoglobulin G 5.82 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 1.66 g/L; Beta 2 Microglobulin 1.4 µg/mL; Lactate Dehydrogenase 1.82 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 5.8 g/dL; Glucose 4.9 mmol/L.

Other clinical attributes
- Day -13: Weight: 83 kg; Height: 177 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Prostate Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1801_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1801_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
